MMRF case MMRF_1817 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/1cd2b2e7-21d4-4e09-b7dc-2178411734b6

Demographics
Sex at birth: male; Age at index: 68 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 68.5 years (25,022 days); ISS stage: I; Days to last known disease status: 1,066 days (2.9 years); Days to last follow up: 1,066 days (2.9 years).
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 92 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 25 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 93 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 26 days; Days to treatment end: 29 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 30 days; Days to treatment end: 93 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 169 days; Days to treatment end: 169 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 170 days; Days to treatment end: 170 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 401 days (1.1 years); Days to treatment end: 432 days (1.2 years).
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 550 days (1.5 years); Days to treatment end: 774 days (2.1 years).
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 947 days (2.6 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -16: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 151 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.13 mg/dL; Immunoglobulin G 6.25 g/L; Immunoglobulin A 0.46 g/L; Immunoglobulin M 0.19 g/L; Beta 2 Microglobulin 1.65 µg/mL; Lactate Dehydrogenase 3.2 µkat/L; Hemoglobin 8.49 mmol/L; Leukocytes 6.2 ×10⁹/L; Absolute Neutrophil 4 ×10⁹/L; Platelets 111 ×10⁹/L; Creatinine 84 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.43 mmol/L; Albumin 41 g/L; Total Protein 6.9 g/dL; Glucose 6.6 mmol/L; C-Reactive Protein 0.076 mg/dL.
- Day 71: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.713 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.1 mg/dL; Immunoglobulin G 4.05 g/L; Immunoglobulin A 0.07 g/L; Immunoglobulin M 0.05 g/L; Beta 2 Microglobulin 1.84 µg/mL.
- Day 156: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.19 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.05 mg/dL; Immunoglobulin G 2.82 g/L; Immunoglobulin A 0.12 g/L; Immunoglobulin M 0.09 g/L; Beta 2 Microglobulin 1.72 µg/mL; Hemoglobin 7.01 mmol/L; Leukocytes 4.1 ×10⁹/L; Absolute Neutrophil 2.45 ×10⁹/L; Platelets 149 ×10⁹/L; Creatinine 76 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.18 mmol/L; Albumin 37 g/L; Total Protein 6 g/dL; Glucose 5.06 mmol/L.
- Day 263: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.42 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.05 mg/dL; Immunoglobulin G 4.02 g/L; Immunoglobulin A 0.23 g/L; Immunoglobulin M 0.29 g/L; Beta 2 Microglobulin 1.41 µg/mL; Lactate Dehydrogenase 2.33 µkat/L; Hemoglobin 8.18 mmol/L; Leukocytes 4.8 ×10⁹/L; Absolute Neutrophil 3.36 ×10⁹/L; Platelets 96 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.35 mmol/L; Albumin 40 g/L; Total Protein 6.5 g/dL; Glucose 5.01 mmol/L.
- Day 382 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.85 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.07 mg/dL; Immunoglobulin G 3.98 g/L; Immunoglobulin A 0.26 g/L; Immunoglobulin M 0.25 g/L; Beta 2 Microglobulin 1.33 µg/mL; Lactate Dehydrogenase 2.5 µkat/L; Hemoglobin 8.06 mmol/L; Leukocytes 9.1 ×10⁹/L; Absolute Neutrophil 7.54 ×10⁹/L; Platelets 85 ×10⁹/L; Creatinine 82.2 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.33 mmol/L; Albumin 42 g/L; Total Protein 6.6 g/dL; Glucose 5.78 mmol/L.
- Day 459: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.751 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.729 mg/dL; Beta 2 Microglobulin 1.57 µg/mL; Lactate Dehydrogenase 2.07 µkat/L; Hemoglobin 7.75 mmol/L; Leukocytes 5.7 ×10⁹/L; Absolute Neutrophil 4.21 ×10⁹/L; Platelets 75 ×10⁹/L; Creatinine 76 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.33 mmol/L; Albumin 42 g/L; Total Protein 6.9 g/dL; Glucose 4.95 mmol/L.
- Day 550 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.22 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.2 mg/dL; Immunoglobulin G 6.21 g/L; Immunoglobulin A 1.14 g/L; Immunoglobulin M 0.21 g/L; Beta 2 Microglobulin 1.48 µg/mL; Lactate Dehydrogenase 2.57 µkat/L; Hemoglobin 7.75 mmol/L; Leukocytes 4.5 ×10⁹/L; Absolute Neutrophil 3.33 ×10⁹/L; Platelets 88 ×10⁹/L; Creatinine 73.4 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.28 mmol/L; Albumin 40 g/L; Total Protein 6.8 g/dL; Glucose 6.27 mmol/L.
- Day 627: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.49 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.09 mg/dL; Immunoglobulin G 6.71 g/L; Immunoglobulin A 1.24 g/L; Immunoglobulin M 0.23 g/L; Beta 2 Microglobulin 1.57 µg/mL; Lactate Dehydrogenase 1.97 µkat/L; Hemoglobin 7.69 mmol/L; Leukocytes 3 ×10⁹/L; Absolute Neutrophil 1.65 ×10⁹/L; Platelets 61 ×10⁹/L; Creatinine 86.6 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.3 mmol/L; Albumin 42 g/L; Total Protein 6.6 g/dL; Glucose 5.28 mmol/L.
- Day 718: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.28 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.07 mg/dL; Immunoglobulin G 8.27 g/L; Immunoglobulin A 1.22 g/L; Immunoglobulin M 0.19 g/L; Beta 2 Microglobulin 1.29 µg/mL; Hemoglobin 7.87 mmol/L; Leukocytes 3.7 ×10⁹/L; Absolute Neutrophil 1.64 ×10⁹/L; Platelets 69 ×10⁹/L; Creatinine 95.5 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.25 mmol/L; Albumin 39 g/L; Total Protein 6.6 g/dL; Glucose 7.81 mmol/L.
- Day 802: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.39 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.99 mg/dL; Immunoglobulin G 8.25 g/L; Immunoglobulin A 1.22 g/L; Immunoglobulin M 0.19 g/L; Hemoglobin 7.32 mmol/L; Leukocytes 3.7 ×10⁹/L; Absolute Neutrophil 2.04 ×10⁹/L; Platelets 55 ×10⁹/L; Creatinine 94.6 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.23 mmol/L; Albumin 39 g/L; Total Protein 6.5 g/dL; Glucose 5.01 mmol/L.
- Day 921 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 5.5 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.98 mg/dL; Immunoglobulin G 7.29 g/L; Immunoglobulin A 1.29 g/L; Immunoglobulin M 0.22 g/L; Beta 2 Microglobulin 5.61 µg/mL; Lactate Dehydrogenase 2.35 µkat/L; Hemoglobin 7.69 mmol/L; Leukocytes 5.7 ×10⁹/L; Absolute Neutrophil 4.06 ×10⁹/L; Platelets 70 ×10⁹/L; Creatinine 93.7 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.25 mmol/L; Albumin 43 g/L; Total Protein 6.9 g/dL; Glucose 6.22 mmol/L.
- Day 975: Hemoglobin 8.06 mmol/L; Leukocytes 3.6 ×10⁹/L; Absolute Neutrophil 1.91 ×10⁹/L; Platelets 73 ×10⁹/L; Creatinine 84 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.3 mmol/L; Albumin 41 g/L; Total Protein 7.3 g/dL; Glucose 6.11 mmol/L.
- Day 1,066: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.6 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.27 mg/dL; Immunoglobulin G 8.64 g/L; Immunoglobulin A 2.09 g/L; Immunoglobulin M 0.36 g/L; Hemoglobin 7.81 mmol/L; Leukocytes 3.5 ×10⁹/L; Absolute Neutrophil 1.91 ×10⁹/L; Platelets 79 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Total Protein 6.7 g/dL; Glucose 6.27 mmol/L.

Other clinical attributes
- Day -16: Weight: 85 kg; Height: 180 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_1817_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -16 days.
- Sample MMRF_1817_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -16 days.
